Gene-level copy-number profile of specimen HCM-CSHL-0730-C25-85A from HCMI case HCM-CSHL-0730-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 67.5 years (24,642 days).
Specimen HCM-CSHL-0730-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8f43ea8-1a4b-4b3c-b0b4-4e4236c5d102.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0730-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/130b8172-011a-4aa3-8ff8-9123b7904f87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,254; copy number 2: 49,304; copy number 3: 4,739; copy number 4: 84; copy number 5: 4; copy number 6: 3; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes, copy number 5: AL031432.2, RHD, SDHDP6.
- chr9:29,254,075–29,826,711, 4 genes, copy number 6–10: AL162388.1, AL353684.1, AL354676.1, ME2P1.

Autosomal genes at a single copy (total copy number 1): 4,253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
